TARGET case TARGET-10-PASWFN — Acute Lymphoblastic Leukemia - Phase III (TARGET-ALL-P3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/807206e3-628a-40b1-8227-81f93c67a21c

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino.

Biospecimens (1 sample)
- Sample TARGET-10-PASWFN-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_Blast_Data_20230727.xlsx, for sample TARGET-10-PASWFN-09A-01D:
- Blast %: 0.9

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_II_Validation_20230727.xlsx:
- Overall Survival Time in Days: 2395
- WBC at Diagnosis: 5.8
- CNS Status at Diagnosis: CNS 1
- Testicular Involvement: No
- MRD Day 29: 2.5
- MRD Day 29 Sensitivity: 0.01
- Bone Marrow Site of Relapse: No
- CNS Site of Relapse: No
- Testes Site of Relapse: No
- Other Site of Relapse: No
- ETV6 RUNX1 Fusion Status: Negative
- TRISOMY 4 10 Status: Negative
- MLL Status: Negative
- BCR ABL1 Status: Negative
- BMA Blasts Day 8: 24
- BMA Blasts Day 15: 26
- BMA Blasts Day 29: 2
- Karyotype: 46,XY[23]
- Down Syndrome: No
- DNA Index: 1
- Cell of Origin: T Cell ALL

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Validation_Supplement_20230727.xlsx:
- BM Blasts at Diagnosis: 90
- Group: LMO1/2
- Lesion: wt
- ETP status: ETP
- Maturation stage: Pre-cortical
